Gene-level copy-number profile of tumor specimen C3L-03362-05 from CPTAC case C3L-03362, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 41.6 years (15,189 days).
Specimen C3L-03362-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9a09b3cd-bde1-4784-bc38-4748aeae17fb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03362-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/76bc6f5f-c6cb-4951-8eaa-be840d87785c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 635; copy number 1: 1,796; copy number 2: 16,866; copy number 3: 22,092; copy number 4: 8,158; copy number 5: 5,163; copy number 6: 1,163; copy number 7: 2,455; copy number 8: 88; copy number 9: 483.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr4:49,486,926–49,524,185, 5 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr9:16,409,503–17,797,124, 13 genes: BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11.
- chr9:18,360,597–18,362,220, 1 gene: AL442638.1.
- chr9:21,058,771–22,214,672, 54 genes: IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr15:21,911,559–22,152,897, 15 genes: ZNF519P3, NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P, AC010760.1, RPS8P10.
- chr16:32,356,981–32,380,049, 2 genes: AC133548.1, ACTR3BP3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,026 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,738,868–248,937,043, 2,448 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:37,032–33,062,797, 571 genes, copy number 7–9 (broad region; genes not listed).
- chr9:39,072,767–39,288,315, 1 gene, copy number 7 (within-gene range 2–7): CNTNAP3.
- chr9:39,191,100–39,191,360, 1 gene, copy number 7: RN7SL640P.
- chr9:39,886,861–39,892,895, 3 genes, copy number 7: RN7SL763P, SNORA70, CR769767.1.
- chr17:1,716,523–1,738,599, 2 genes, copy number 8 (within-gene range 5–8): WDR81, AC130343.1.

Autosomal genes at a single copy (total copy number 1): 1,156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
